Somatic mutation profile of tumor specimen 0DTLGI from CCDI case PBCJKN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 6.6 years (2,416 days).
Specimen 0DTLGI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60c63c24-9f1b-4dd1-9728-17739f9eac2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTLGD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0039b080-a4c5-4c76-b883-1ba08df1bbc0

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 5, Silent 5, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD2 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 68/1473 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs1344526196, COSV54876867; called by muse, mutect2
- BUD13 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 76/743 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs759334959; called by muse, mutect2, varscan2
- DROSHA | c.3886C>T p.R1296* | Nonsense Mutation (SNP) | VAF 373/1271 reads (29%) | catalogued as rs1174002360; called by muse, mutect2, varscan2
- IPMK | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 262/1591 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.316); catalogued as COSV64243508; called by muse, mutect2, varscan2
- MYO7A | c.4576C>T p.R1526C | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1159604055; called by muse, mutect2, varscan2
- OR4A5 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 351/927 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1178535190, COSV60523502; called by muse, varscan2
- PRELID2 | c.364G>A p.E122K (on ENST00000334744 / NM_182960.4; = p.E81K on NM_138492.6) | Missense Mutation (SNP) | VAF 100/1694 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58281714; called by muse, mutect2
- TTC24 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 104/870 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1286908205, COSV100964324; called by muse, mutect2
- ATP1A1 | c.2300T>C p.L767P | Missense Mutation (SNP) | VAF 94/1096 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC71 | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 35/996 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2
- GRIA2 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 74/1910 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP15 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 48/1469 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5M8 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 178/1122 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- USP26 | c.2212C>T p.Q738* | Nonsense Mutation (SNP) | VAF 72/1340 reads (5%) | called by muse, mutect2
- ABCA7 | c.840C>T p.S280= | Silent (SNP) | VAF 80/948 reads (8%) | called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 24/484 reads (5%) | catalogued as rs1167537044; called by muse, mutect2
- KMT2A | c.666A>G p.R222= | Silent (SNP) | VAF 50/1136 reads (4%) | called by muse, mutect2
- NHS | c.66C>T p.G22= | Silent (SNP) | VAF 237/882 reads (27%) | called by muse, mutect2, varscan2
- TRPM1 | c.3837A>G p.G1279= | Silent (SNP) | VAF 217/1247 reads (17%) | called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 8/158 reads (5%) | catalogued as rs1262556378; called by muse, mutect2
- ANKFY1 | c.10+252C>T | Intron (SNP) | VAF 155/1072 reads (14%) | catalogued as rs1191762510; called by muse, mutect2, varscan2
- ATP1A1 | c.2293+53G>T | Intron (SNP) | VAF 68/636 reads (11%) | called by mutect2, varscan2
- DEPDC5 | c.*798C>A | 3'UTR (SNP) | VAF 33/768 reads (4%) | called by muse, mutect2
- TJP2 | c.1521-25C>T | Intron (SNP) | VAF 110/967 reads (11%) | called by muse, mutect2, varscan2
- UQCRC2 | c.389+30G>T | Intron (SNP) | VAF 55/737 reads (7%) | called by muse, mutect2
